Somatic mutation profile of tumor specimen C3L-06424-02 (aliquot CPT0335090006) from CPTAC case C3L-06424, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.2 years (25,996 days).
Specimen C3L-06424-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Back; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4613f73-a19e-4f95-a8ce-fb45115ab185.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06424-31 (Blood Derived Normal), aliquot CPT0335060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b8de950-ecec-452d-b45f-11b67a863ef8

The open-access MAF lists 767 somatic variants for this specimen: 487 protein-altering or splice-affecting, 247 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 447, Silent 247, Nonsense Mutation 24, Intron 20, Splice Site 7, Splice Region 6, RNA 4, Frame Shift Del 3, 5'Flank 3, 3'Flank 3, 5'UTR 2, 3'UTR 1.

Variants (750 of 767; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MMUT | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 44/580 reads (8%) | catalogued as rs398123278, CM060346, COSV51275543; ClinVar: pathogenic; called by muse, mutect2
- SYNE1 | c.10145+1G>A p.X3382_splice (on ENST00000367255 / NM_182961.4; = p.X3389_splice on NM_033071.3) | Splice Site (SNP) | VAF 37/280 reads (13%) | catalogued as rs1563391747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770362206, COSV60624306; called by muse, mutect2, varscan2
- AC090517.4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV50996448; called by muse, mutect2, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by muse, mutect2, varscan2
- ADAM18 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 40/248 reads (16%) | catalogued as rs1040913709, COSV104378207; called by muse, mutect2, varscan2
- ADAM30 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 73/476 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs267597954; called by muse, mutect2, varscan2
- ADAM7 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs867000380, COSV51544305; called by muse, mutect2, varscan2
- ADAMTS5 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs748491619, COSV53177561; called by muse, mutect2, varscan2
- ADAT3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 89/492 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs761753603; called by muse, mutect2, varscan2
- ADGRV1 | c.15106G>A p.D5036N | Missense Mutation (SNP) | VAF 240/561 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867504287, COSV67991999; called by muse, mutect2, varscan2
- AKAP9 | c.6386T>C p.V2129A (on ENST00000359028; = p.V2097A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/435 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.195); catalogued as COSV100662703; called by muse, mutect2, varscan2
- AKR1B15 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 62/508 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV71152918; called by muse, mutect2, varscan2
- AMER3 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 92/514 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as rs745874912; called by muse, mutect2, varscan2
- AQP7 | c.673A>C p.I225L | Missense Mutation (SNP) | VAF 103/550 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV53019212; called by muse, mutect2, varscan2
- ARFGEF2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100904086, COSV64213383; called by muse, mutect2, varscan2
- ARHGEF40 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780625866, COSV53882459; called by muse, mutect2, varscan2
- ARID2 | c.5348C>T p.S1783L | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1175264280, COSV57598770; called by muse, mutect2, varscan2
- ARMC4 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as CM157435; called by muse, mutect2, varscan2
- ASPHD2 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 100/548 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99313146; called by muse, mutect2, varscan2
- AXL | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV56563356; called by muse, mutect2, varscan2
- BSND | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 97/513 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64871379; called by muse, mutect2, varscan2
- BTBD8 | c.3497C>T p.S1166L (on ENST00000636805 / NM_001376131.1; = p.S653L on NM_015237.4) | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1402170706, COSV64884148; called by muse, mutect2, varscan2
- C1QTNF12 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 91/515 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767206628, COSV57803685; called by muse, mutect2, varscan2
- C1orf94 | c.1446G>A p.Q482= (on ENST00000488417 / NM_001134734.2; = p.Q292= on NM_032884.5) | Splice Region (SNP) | VAF 43/263 reads (16%) | catalogued as rs747103106; called by muse, mutect2, varscan2
- C6orf132 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.243); catalogued as rs1324569864; called by muse, mutect2
- C6orf132 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 64/675 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1230743016; called by muse, mutect2
- CCDC68 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 60/282 reads (21%) | catalogued as COSV100491976; called by muse, mutect2, varscan2
- CDH11 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 66/419 reads (16%) | catalogued as COSV51762296; called by muse, mutect2, varscan2
- CFAP53 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV68352807; called by muse, mutect2, varscan2
- CFHR2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs867746464, COSV66380395; called by muse, mutect2, varscan2
- CHRDL2 | c.82+1G>A p.X28_splice | Splice Site (SNP) | VAF 75/379 reads (20%) | catalogued as rs1390735747; called by muse, mutect2, varscan2
- CMYA5 | c.8576C>T p.S2859F | Missense Mutation (SNP) | VAF 84/638 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV71404103; called by muse, mutect2, varscan2
- CNTN5 | c.2689A>C p.K897Q | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.691); catalogued as rs749029208; called by muse, mutect2, varscan2
- COL15A1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100898094; called by muse, mutect2, varscan2
- COL1A2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 63/618 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs1054900983; called by muse, mutect2, varscan2
- CPVL | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV55304700, COSV55308607; called by muse, mutect2, varscan2
- CPZ | c.460G>A p.D154N (on ENST00000360986 / NM_001014447.3; = p.D143N on NM_003652.3) | Missense Mutation (SNP) | VAF 79/402 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs868300405; called by muse, mutect2, varscan2
- CRB1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV66330460; called by muse, varscan2
- CSGALNACT2 | c.1337-1G>A p.X446_splice | Splice Site (SNP) | VAF 35/235 reads (15%) | catalogued as COSV65678595; called by muse, mutect2, varscan2
- CSMD1 | c.3614G>T p.G1205V (on ENST00000520002; = p.G1204V on NM_033225.6) | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59381907; called by muse, mutect2
- CSMD1 | c.1852G>A p.E618K (on ENST00000520002; = p.E617K on NM_033225.6) | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV59285185; called by muse, mutect2, varscan2
- CSNK2A1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 126/577 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1397626830; called by muse, mutect2, varscan2
- CTNND2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 21/590 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1445784718, COSV58865546; called by muse, mutect2
- CWC22 | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763690180; called by muse, mutect2, varscan2
- CX3CL1 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 90/561 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV50055448; called by muse, mutect2, varscan2
- CYLC2 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV66337427; called by muse, mutect2, varscan2
- CYP2F1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs145467892; called by muse, mutect2, varscan2
- CYP4F3 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs760254615; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DLG4 | c.1538C>T p.S513L (on ENST00000399506 / NM_001321075.3; = p.S556L on NM_001365.4) | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs376874609; called by muse, mutect2, varscan2
- DNAH5 | c.12415C>T p.P4139S | Missense Mutation (SNP) | VAF 91/518 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV54209617; called by muse, mutect2, varscan2
- DNAH5 | c.6764G>A p.R2255Q | Missense Mutation (SNP) | VAF 102/608 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1317585354, COSV54235046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.11405C>T p.S3802L | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556015158, COSV56759154; called by muse, mutect2, varscan2
- DNAH9 | c.2145G>A p.M715I | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs755778334, COSV52367085; called by muse, mutect2, varscan2
- DOCK1 | c.1059-7C>T | Splice Region (SNP) | VAF 65/412 reads (16%) | catalogued as COSV54763762; called by muse, mutect2, varscan2
- DOCK2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56977947; called by muse, mutect2, varscan2
- DOCK3 | c.4976C>T p.P1659L | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs775087055, COSV56550338; called by muse, mutect2, varscan2
- DPM1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1052184543, COSV54867685; called by muse, mutect2, varscan2
- DPP6 | c.1753G>A p.A585T (on ENST00000377770 / NM_001364500.2; = p.A523T on NM_001936.5) | Missense Mutation (SNP) | VAF 91/482 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs375516548; called by muse, mutect2, varscan2
- DPYD | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs377169736, COSV60078822, COSV60082730; called by muse, mutect2, varscan2
- EFCAB8 | c.2632-1G>A p.X878_splice | Splice Site (SNP) | VAF 81/261 reads (31%) | catalogued as rs1428707774; called by muse, mutect2, varscan2
- EIF4G3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.253); catalogued as COSV51677124; called by muse, mutect2, varscan2
- EP400 | c.6713C>T p.P2238L | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57781687; called by muse, mutect2, varscan2
- ERC2 | c.2727G>A p.M909I | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV55601097; called by muse, mutect2, varscan2
- ERC2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 85/473 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV55612384; called by muse, mutect2, varscan2
- EREG | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs867627418; called by muse, mutect2, varscan2
- EYA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58159030; called by muse, mutect2, varscan2
- FAM71F2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 58/582 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs200938500, COSV66352050; called by muse, mutect2
- FAT3 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369038969; called by muse, mutect2, varscan2
- FAT3 | c.3152C>T p.S1051F | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.855); catalogued as rs767315696; called by muse, mutect2, varscan2
- FAT4 | c.14176C>T p.P4726S | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV58682700; called by muse, mutect2, varscan2
- FGFR2 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1224606327, CM118255, COSV60652082; called by muse, mutect2, varscan2
- FGFRL1 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 26/771 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1490964364; called by muse, mutect2
- FKBP6 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs371070079; called by muse, mutect2, varscan2
- FLG | c.11545G>A p.E3849K | Missense Mutation (SNP) | VAF 125/676 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV64242921; called by muse, mutect2, varscan2
- FMO2 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 85/564 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV52946866; called by muse, mutect2, varscan2
- FRAS1 | c.7131G>A p.M2377I | Missense Mutation (SNP) | VAF 67/418 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV53617063; called by muse, mutect2, varscan2
- FRMPD2 | c.3914C>T p.S1305L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1206096713; called by mutect2, varscan2
- FRMPD4 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs751943219, COSV66215063; called by muse, mutect2
- FSTL5 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.634); catalogued as COSV60188911; called by muse, mutect2, varscan2
- FUT9 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV56141495; called by muse, mutect2, varscan2
- FZD6 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 67/407 reads (16%) | catalogued as rs777689471, COSV62472150; called by muse, mutect2, varscan2
- GAD1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs1273863798; called by muse, mutect2, varscan2
- GATAD2B | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 135/497 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as COSV64086180; called by muse, mutect2, varscan2
- GFRA2 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1026794849, COSV60780779; called by muse, mutect2, varscan2
- GPR31 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 81/519 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs779326200; called by muse, mutect2, varscan2
- GPT2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV60838636; called by muse, mutect2, varscan2
- GRIK1 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as rs1346295351, COSV58723767; called by muse, mutect2, varscan2
- GRIN2D | c.3686C>T p.P1229L | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.043); catalogued as rs1350753867; called by muse, mutect2, varscan2
- GZMA | c.357G>A p.Q119= | Splice Region (SNP) | VAF 37/252 reads (15%) | catalogued as COSV99956636; called by muse, mutect2, varscan2
- GZMK | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 106/547 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751541408, COSV50248313; called by muse, mutect2, varscan2
- HCFC1 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV60068994; called by muse, mutect2, varscan2
- HECW2 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 83/391 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53665794, COSV53668820; called by muse, mutect2, varscan2
- HELB | c.3245C>T p.T1082I | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1427655751; called by muse, mutect2, varscan2
- HIVEP3 | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56013963; called by muse, mutect2, varscan2
- HOATZ | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs771451441, COSV60441684; called by muse, mutect2, varscan2
- HS6ST3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.084); catalogued as rs1331474154, COSV65014061; called by muse, mutect2, varscan2
- HSD3B2 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV65593600; called by muse, mutect2, varscan2
- HYDIN | c.9904G>A p.D3302N | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs773404736, COSV66881391; called by muse, mutect2, varscan2
- IGHV1-46 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1555524836; called by muse, mutect2, varscan2
- IL1RL2 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs866058726, COSV51812942, COSV51816541; called by muse, mutect2, varscan2
- ILDR2 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 97/588 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54830647, COSV54834633; called by muse, mutect2, varscan2
- INTS1 | c.5999C>T p.S2000F | Missense Mutation (SNP) | VAF 22/795 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs932787920; called by muse, mutect2
- IRGC | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV99746157; called by muse, varscan2
- ITGAE | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs189112267, COSV53989487; called by muse, mutect2, varscan2
- ITGAX | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51651554; called by muse, mutect2, varscan2
- ITIH5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 90/470 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs747038918, COSV53670364; called by muse, mutect2, varscan2
- KCND2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 184/794 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs1285609642, COSV58576385; called by muse, mutect2, varscan2
- KCNJ1 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60662295; called by muse, mutect2, varscan2
- KIAA1217 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 89/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64610430; called by muse, mutect2, varscan2
- KIAA1217 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV56815882; called by muse, mutect2, varscan2
- KIAA1328 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.455); catalogued as rs756834650, COSV54449854; called by muse, mutect2, varscan2
- KLHL6 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs141833676; called by muse, mutect2, varscan2
- KLK12 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs546276676, COSV51576919; called by muse, mutect2, varscan2
- KRT26 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1567675203; called by muse, mutect2, varscan2
- KRT3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 108/537 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58814682; called by muse, mutect2, varscan2
- LCE5A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 199/674 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.485); catalogued as rs1423735491, COSV57500082; called by muse, mutect2, varscan2
- LGR6 | c.2005G>A p.V669I (on ENST00000367278 / NM_001017403.1; = p.V617I on NM_021636.3) | Missense Mutation (SNP) | VAF 191/618 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs143684053; called by muse, mutect2, varscan2
- LMLN2 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1218375425; called by muse, mutect2, varscan2
- LRIT1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 57/402 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs766085491, COSV64512155; called by muse, mutect2, varscan2
- LRRC7 | c.1192C>T p.L398F (on ENST00000651989 / NM_001370785.2; = p.L365F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99226490; called by muse, mutect2, varscan2
- LRTM1 | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 73/425 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55546789; called by muse, mutect2, varscan2
- MAP3K13 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV54000607; called by muse, mutect2, varscan2
- MAP3K19 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748760359, COSV100209401, COSV59640296; called by muse, mutect2, varscan2
- MMP1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100188147, COSV59510400; called by muse, mutect2, varscan2
- MMP24 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 85/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867807473, COSV55768690; called by muse, mutect2, varscan2
- MORN1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 82/495 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV101047968; called by muse, mutect2, varscan2
- MROH9 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV63010437; called by muse, mutect2, varscan2
- MTUS2 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 87/468 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs747494603, COSV70916004; called by muse, mutect2, varscan2
- MUC16 | c.26377C>T p.H8793Y | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.211); catalogued as COSV67481920; called by muse, mutect2, varscan2
- MUC16 | c.9935C>T p.S3312F | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs367755443; called by muse, mutect2, varscan2
- MUC16 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 81/461 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); catalogued as rs370098137; called by muse, mutect2, varscan2
- MUC4 | c.7252C>T p.P2418S | Missense Mutation (SNP) | VAF 114/2156 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as rs776494023; called by muse, mutect2
- MYH7B | c.5056G>A p.E1686K | Missense Mutation (SNP) | VAF 120/699 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV99327787; called by muse, mutect2, varscan2
- MYO5B | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs868716202; called by muse, mutect2, varscan2
- MYOCD | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs372928138; called by muse, mutect2, varscan2
- MYRIP | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as COSV100219998, COSV56881670; called by muse, mutect2, varscan2
- NAA11 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 85/477 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs1298822356; called by muse, mutect2, varscan2
- NKAIN2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs767024716, COSV63677421; called by muse, mutect2, varscan2
- NLRP10 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 90/553 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.387); catalogued as rs866417661, COSV60781132; called by muse, varscan2
- NLRP11 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 72/475 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs141720579; called by muse, mutect2, varscan2
- NLRP14 | c.2684C>G p.S895C | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100205343; called by muse, mutect2, varscan2
- NLRP5 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1479170157; called by muse, mutect2, varscan2
- NPTX2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 73/814 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs371914516; called by muse, mutect2
- NRK | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs763061332, COSV54591426; called by muse, mutect2, varscan2
- NXF3 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 87/228 reads (38%) | catalogued as COSV67704279; called by muse, mutect2, varscan2
- NXPE2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 48/274 reads (18%) | catalogued as rs998196966, COSV64940962; called by muse, mutect2, varscan2
- OR13C5 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV66165241; called by muse, mutect2
- OR13F1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs752978468; called by mutect2, varscan2
- OR1L1 | c.1007C>T p.P336L (on ENST00000373686; = p.P286L on NM_001005236.3) | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs372290682; called by muse, mutect2, varscan2
- OR2H1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 157/602 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs373932418, COSV101009771; called by muse, mutect2, varscan2
- OR2T33 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775475303, COSV58813890; called by muse, mutect2, varscan2
- OR51B2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60916674; called by muse, mutect2, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR52N4 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57893087; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR7D4 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 84/490 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV58071624; called by muse, mutect2, varscan2
- OR8D2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100659130, COSV62488279; called by muse, mutect2, varscan2
- OSBPL3 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749672339; called by muse, mutect2, varscan2
- PABPC4L | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421010169; called by muse, mutect2, varscan2
- PADI6 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1214829811; called by muse, mutect2, varscan2
- PAH | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as CM930544, COSV61015784; called by muse, mutect2, varscan2
- PAIP1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 120/355 reads (34%) | catalogued as rs760516043, COSV100166565; called by muse, mutect2, varscan2
- PANX2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 126/733 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs746496067; called by muse, mutect2, varscan2
- PAPLN | c.1286C>T p.P429L (on ENST00000554301; = p.P402L on NM_173462.4) | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs530218324, COSV53712491; called by muse, mutect2, varscan2
- PCDHA8 | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV65329586; called by muse, mutect2, varscan2
- PCLO | c.8059C>T p.P2687S | Missense Mutation (SNP) | VAF 65/619 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs771484832, COSV100428371, COSV61614828; called by muse, mutect2, varscan2
- PCLO | c.4102G>A p.D1368N | Missense Mutation (SNP) | VAF 73/683 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs533061339, COSV61638785, COSV61659459; called by muse, mutect2, varscan2
- PCNX1 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777713016, COSV53096036, COSV53098198; called by muse, mutect2, varscan2
- PDE1C | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 79/560 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV58502785; called by muse, mutect2, varscan2
- PDK3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64793416; called by muse, mutect2, varscan2
- PLEKHG4 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 81/446 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100846483; called by muse, mutect2, varscan2
- PLXDC2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV101024979, COSV65914772; called by muse, mutect2
- PMP22 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1311837830, COSV56603605; called by muse, mutect2, varscan2
- POF1B | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV53135398; called by muse, mutect2, varscan2
- POLRMT | c.1496C>T p.T499I | Missense Mutation (SNP) | VAF 83/469 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs762074939; called by muse, mutect2, varscan2
- POTEC | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV62804333; called by muse, mutect2
- PPP1R13B | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968897903, COSV52449070, COSV52453922; called by muse, mutect2, varscan2
- PPP1R37 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 127/663 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); catalogued as rs1466879978; called by muse, mutect2, varscan2
- PPP6C | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV65206937; called by muse, mutect2, varscan2
- PPP6R3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55735440; called by muse, mutect2, varscan2
- PRAMEF1 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 58/475 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs199886880; called by muse, mutect2, varscan2
- PRAMEF2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); catalogued as rs140567467; called by muse, mutect2
- PRPF4B | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs775187928, COSV61784512; called by muse, mutect2, varscan2
- PSG6 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 85/575 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs1384959281; called by muse, mutect2, varscan2
- PTPRK | c.2227C>T p.P743S (on ENST00000368215 / NM_001291984.2; = p.P744S on NM_002844.4) | Missense Mutation (SNP) | VAF 96/382 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV63905119; called by muse, mutect2, varscan2
- RALGAPA1 | c.4348C>T p.P1450S | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.082); catalogued as COSV51892962; called by muse, mutect2, varscan2
- RASGRP2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV62450883; called by muse, mutect2, varscan2
- RASIP1 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765379837, COSV55807501; called by muse, mutect2, varscan2
- RBM20 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 111/546 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as rs1279998131; called by muse, mutect2, varscan2
- RGPD3 | c.3390G>A p.W1130* | Nonsense Mutation (SNP) | VAF 128/666 reads (19%) | catalogued as rs1364751422; called by muse, mutect2, varscan2
- RGS20 | c.521C>T p.S174L (on ENST00000297313 / NM_170587.4; = p.S27L on NM_003702.4) | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs775903177; called by muse, mutect2, varscan2
- RIN3 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 73/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367766872; called by muse, mutect2, varscan2
- RNF133 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 96/783 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57355183; called by muse, mutect2, varscan2
- RNF25 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs534831838; called by muse, mutect2, varscan2
- RYR1 | c.3022G>C p.A1008P | Missense Mutation (SNP) | VAF 136/628 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.29); catalogued as COSV62099777; called by muse, mutect2, varscan2
- SALL1 | c.2960G>A p.G987E | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV99175169; called by muse, mutect2, varscan2
- SALL3 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.726); catalogued as rs890658695; called by muse, mutect2, varscan2
- SAMD9L | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 182/516 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767921026, COSV59080585; called by muse, mutect2, varscan2
- SATB1 | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100113444; called by muse, mutect2, varscan2
- SBSN | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 103/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101510040; called by muse, mutect2, varscan2
- SCLT1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs778704461; called by muse, mutect2, varscan2
- SCN11A | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs868856046, COSV56573653; called by muse, mutect2, varscan2
- SERPINB10 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 65/417 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs267605235, COSV53072971; called by muse, mutect2
- SHISAL1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 202/679 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs757448925, COSV66987684, COSV66987790; called by muse, mutect2, varscan2
- SIGLEC5 | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 91/453 reads (20%) | catalogued as COSV55783043; called by muse, mutect2, varscan2
- SIPA1L1 | c.3105-1G>A p.X1035_splice | Splice Site (SNP) | VAF 39/171 reads (23%) | catalogued as COSV100665484; called by muse, mutect2, varscan2
- SLC12A3 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 89/449 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs777612082, CM961291, COSV99343912; called by muse, mutect2, varscan2
- SLC17A3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57761311; called by muse, mutect2
- SLC1A7 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 71/412 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs201914790, COSV101019302, COSV65195313; called by muse, mutect2, varscan2
- SLC24A3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs765357990; called by muse, mutect2, varscan2
- SLC35F1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs767401575, COSV64502186; called by muse, mutect2, varscan2
- SLC6A19 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs894693588, COSV100443598; called by muse, mutect2, varscan2
- SLC7A10 | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 66/399 reads (17%) | catalogued as rs752048743; called by muse, mutect2, varscan2
- SLC9A4 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs957584201, COSV99762804; called by muse, mutect2, varscan2
- SORL1 | c.3263G>A p.G1088E | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs753319585; called by muse, mutect2, varscan2
- SPTA1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 160/502 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750863150, COSV63748627; called by muse, mutect2, varscan2
- ST6GAL2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 65/368 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV62418437; called by muse, mutect2, varscan2
- ST7 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 278/786 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as COSV99622090; called by muse, mutect2, varscan2
- STARD9 | c.3545C>T p.S1182F | Missense Mutation (SNP) | VAF 76/496 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV51903803; called by muse, mutect2, varscan2
- STX4 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as COSV58268016; called by muse, mutect2, varscan2
- SUPT20H | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 46/302 reads (15%) | catalogued as rs926244369, COSV62247895; called by muse, mutect2, varscan2
- SYNE1 | c.10145G>A p.S3382N (on ENST00000367255 / NM_182961.4; = p.S3389N on NM_033071.3) | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54920029; called by muse, mutect2, varscan2
- TACR3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 106/496 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866456567, COSV59197957; called by muse, mutect2, varscan2
- TALDO1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1225410619, COSV100032646; called by muse, mutect2, varscan2
- TBC1D2B | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 75/480 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs776731092, COSV56038860; called by muse, mutect2, varscan2
- TDRD10 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1429721345; called by muse, mutect2, varscan2
- TINAG | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.161); catalogued as COSV99449471; called by muse, mutect2, varscan2
- TLR4 | c.645G>A p.M215I (on ENST00000355622 / NM_138554.5; = p.M175I on NM_003266.4) | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62923936; called by muse, mutect2, varscan2
- TLR5 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 83/513 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60557801; called by muse, mutect2, varscan2
- TMPRSS11B | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 79/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60291335; called by muse, mutect2, varscan2
- TNNT3 | c.483G>A p.M161I (on ENST00000397301 / NM_001367846.1; = p.M150I on NM_006757.4) | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV99547818; called by muse, mutect2, varscan2
- TOPAZ1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 66/475 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.389); catalogued as rs776510376, COSV59069407; called by muse, mutect2, varscan2
- TOPAZ1 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1308681999; called by muse, mutect2, varscan2
- TRANK1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 107/520 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV57143107; called by muse, mutect2, varscan2
- TRAV25 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219742521; called by muse, mutect2, varscan2
- TRDN | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.978); catalogued as COSV100521997; called by muse, mutect2, varscan2
- TRIM55 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52547669; called by muse, mutect2, varscan2
- TRPS1 | c.1660C>T p.H554Y (on ENST00000220888 / NM_001330599.2; = p.H567Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/495 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55230331; called by muse, mutect2, varscan2
- TRPV6 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 154/663 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs150734746; called by muse, mutect2, varscan2
- TSPAN18 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs144981841; called by muse, mutect2, varscan2
- TTN | c.102758G>A p.G34253E (on ENST00000591111; = p.G26829E on NM_003319.4) | Missense Mutation (SNP) | VAF 60/267 reads (22%) | PolyPhen probably damaging (1); catalogued as rs867480007, COSV60105851; called by muse, mutect2, varscan2
- TTN | c.40306G>A p.E13436K (on ENST00000591111; = p.E6012K on NM_003319.4) | Missense Mutation (SNP) | VAF 84/497 reads (17%) | PolyPhen possibly damaging (0.894); catalogued as COSV59890889; called by muse, mutect2, varscan2
- TTN | c.3920G>A p.G1307D (on ENST00000591111; = p.G1261D on NM_003319.4) | Missense Mutation (SNP) | VAF 41/317 reads (13%) | PolyPhen possibly damaging (0.559); catalogued as rs776940545; called by muse, mutect2, varscan2
- UBAP1L | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 81/682 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1181080382; called by muse, mutect2, varscan2
- UBR5 | c.5920C>T p.R1974C | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs143552597; called by muse, mutect2, varscan2
- UNC79 | c.5374G>A p.E1792K (on ENST00000393151 / NM_001346218.2; = p.E1615K on NM_020818.5) | Missense Mutation (SNP) | VAF 107/610 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs199539496, COSV56386717; called by muse, mutect2, varscan2
- UNC80 | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99778513; called by muse, mutect2, varscan2
- VASH2 | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 81/559 reads (14%) | catalogued as COSV55118662; called by muse, mutect2, varscan2
- VAX2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 99/582 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs781959585, COSV52267787; called by muse, mutect2, varscan2
- VWA5A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 82/410 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs201601409, COSV63707493; called by muse, mutect2, varscan2
- VWA5A | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63707347; called by muse, mutect2, varscan2
- YBX2 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 100/532 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1395251102; called by muse, mutect2, varscan2
- ZBTB25 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 15/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67198538; called by muse, mutect2
- ZC4H2 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV62001654; called by muse, mutect2, varscan2
- ZFAND1 | c.59T>A p.F20Y | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55109017; called by muse, mutect2, varscan2
- ZFYVE16 | c.4189G>A p.V1397I | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.759); catalogued as rs756923246; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.136); catalogued as rs1555489218; called by muse, mutect2, varscan2
- ZNF207 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs901246687; called by muse, mutect2, varscan2
- ZNF214 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV104376282; called by muse, mutect2, varscan2
- ZNF358 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1441454451; called by muse, mutect2, varscan2
- ZNF532 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs753958965, COSV100266065; called by muse, mutect2, varscan2
- ZNF560 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56871629; called by muse, mutect2, varscan2
- ZNF786 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 250/767 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs765692939, COSV60277210, COSV60277531; called by muse, mutect2, varscan2
- ZNF827 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1339127239, COSV65230365; called by muse, mutect2, varscan2
- ZNF835 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 95/557 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs745763305; called by muse, mutect2, varscan2
- AATK | c.1912T>A p.F638I (on ENST00000326724 / NM_001080395.3; = p.F535I on NM_004920.2) | Missense Mutation (SNP) | VAF 232/778 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCC3 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACBD5 | c.1066G>A p.V356I (on ENST00000375888 / NM_001352568.1; = p.V347I on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/454 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM21 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 56/350 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 72/467 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS20 | c.4949A>C p.N1650T | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS7 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, mutect2
- ADGRF1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.047); called by muse, mutect2
- ADGRL2 | c.1840G>A p.D614N (on ENST00000370717 / NM_001366005.1; = p.D601N on NM_012302.4) | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- AGRN | c.5237T>G p.V1746G | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- ALOX12B | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, varscan2
- ANK1 | c.1937G>A p.G646D | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ARID2 | c.4726C>T p.Q1576* | Nonsense Mutation (SNP) | VAF 60/415 reads (14%) | called by muse, mutect2, varscan2
- ARPP21 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ASXL3 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP13A1 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAG6 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 75/848 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- BAZ2B | c.5113C>T p.P1705S | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- BHMT | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BRD1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 96/540 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 79/543 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1S | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C3 | c.4979G>A p.G1660E | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf20 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CASP4 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CATIP | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATIP | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 67/424 reads (16%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATSPER2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CBLB | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD1E | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CDC45 | c.1490_1499del p.L497Rfs*5 | Frame Shift Del (DEL) | VAF 65/510 reads (13%) | called by mutect2, pindel, varscan2
- CEACAM21 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 90/528 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CELSR1 | c.8012G>A p.G2671E | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP221 | c.1679T>A p.I560N | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CFHR5 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CHADL | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 86/601 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIT | c.5438C>T p.S1813F | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CLEC18B | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.296); called by muse, mutect2
- CNNM1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 126/653 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- COL1A2 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 68/461 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL7A1 | c.3276+1G>A p.X1092_splice | Splice Site (SNP) | VAF 57/304 reads (19%) | called by muse, mutect2, varscan2
- COL7A1 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPE | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- CPN2 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 108/469 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1 | c.5551C>T p.P1851S | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CRACR2A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 115/541 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRX | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 109/576 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CSNK2A1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 127/574 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CTAGE6 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 51/1547 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CTNS | c.225A>G p.E75= | Splice Region (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- CX3CL1 | c.512C>G p.P171R | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DAW1 | c.882A>C p.K294N | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DCLK3 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 83/427 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCLK3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 89/455 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMAC2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DOCK8 | c.3121-1G>A p.X1041_splice | Splice Site (SNP) | VAF 50/219 reads (23%) | called by muse, mutect2, varscan2
- DOCK8 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DPY19L1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 139/507 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD2 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DZANK1 | c.2092G>A p.G698R (on ENST00000262547 / NM_001099407.1; = p.G505R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ECE2 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 103/549 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECT2 | c.385_387delinsT p.V129Cfs*10 (on ENST00000392692 / NM_001349098.2; = p.V98Cfs*10 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/417 reads (15%) | called by pindel, varscan2*
- EFCAB13 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ELAVL3 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 91/474 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENG | c.1042G>C p.D348H | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ENGASE | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 88/531 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ENPP2 | c.426del p.H143Ifs*10 | Frame Shift Del (DEL) | VAF 34/331 reads (10%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2564C>T p.S855F (on ENST00000389672 / NM_001080448.3; = p.S247F on NM_173655.4) | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA8 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 85/527 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB1 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F2R | c.1251C>A p.N417K | Missense Mutation (SNP) | VAF 231/475 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FREM1 | c.5294G>A p.R1765K | Missense Mutation (SNP) | VAF 70/396 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM3 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GGT6 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 81/531 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GP5 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GRIK3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 73/446 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GRK3 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, varscan2
- GRM7 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- GSTA4 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- GSX1 | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 28/666 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- GUCY1A1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 90/504 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HDAC3 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.10531G>A p.E3511K | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2
- HYDIN | c.13656G>A p.M4552I | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL13RA2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- IL4R | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- INPP5E | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 100/535 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IP6K3 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 50/605 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IRGC | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 96/537 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, varscan2
- ITGB4 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- KCNJ10 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 61/486 reads (13%) | called by muse, mutect2, varscan2
- KCTD3 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KIAA0753 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KIAA1217 | c.2734C>T p.H912Y | Missense Mutation (SNP) | VAF 71/503 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLC3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP4-6 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 219/1104 reads (20%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- KRTAP5-7 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- LAMB1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 262/640 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- LBX1 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 101/627 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- LEFTY1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 146/466 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LENEP | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 67/451 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LIMCH1 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LIPH | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LMO3 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- LYST | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 178/651 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MAP1A | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP1A | c.7870C>T p.L2624F | Missense Mutation (SNP) | VAF 114/558 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- MAP2 | c.3071A>C p.E1024A | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- MMP19 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 91/502 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MRC1 | c.2720G>A p.G907E | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2721G>A p.G907= | Splice Region (SNP) | VAF 37/254 reads (15%) | called by muse, mutect2, varscan2
- MUC5AC | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.18); called by muse, mutect2, varscan2
- MUC6 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MUSK | c.2603G>T p.S868I | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7B | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 77/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NANOG | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.82); called by muse, mutect2
- NANOGP8 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NBEA | c.5141C>T p.S1714L | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NF1 | c.5051C>T p.S1684F (on ENST00000358273 / NM_001042492.3; = p.S1663F on NM_000267.3) | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NLRP7 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRX1 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 79/423 reads (19%) | called by muse, mutect2, varscan2
- NOS1 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- NOVA1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- NOVA2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NOX3 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPY5R | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 79/455 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- NT5E | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 46/620 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- NUDT9 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR14C36 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 138/532 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR5L2 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OSBP2 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 190/646 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OSBPL1A | c.2191A>T p.I731L (on ENST00000319481 / NM_080597.4; = p.I218L on NM_018030.4) | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- OTOP3 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 95/400 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PATE4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PATJ | c.3938A>C p.K1313T | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PCLO | c.4711G>A p.G1571S | Missense Mutation (SNP) | VAF 170/551 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCOLCE2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PDZD2 | c.3548G>A p.G1183E | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- PDZD3 | c.1529G>A p.G510E (on ENST00000531114; = p.G430E on NM_024791.4) | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PFAS | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PFN3 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 282/1065 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PIGV | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 73/452 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIWIL2 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PLB1 | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPM1N | c.1059A>T p.E353D | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PPP1R12A | c.2702dup p.Y901* | Nonsense Mutation (INS) | VAF 80/399 reads (20%) | called by mutect2, pindel, varscan2
- PRND | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PRSS53 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 85/494 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG1 | c.708C>T p.L236= | Splice Region (SNP) | VAF 64/327 reads (20%) | called by muse, mutect2, varscan2
- PSMD5 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 79/448 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PSME3 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRA | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 215/656 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRB | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RASGRF2 | c.1089A>C p.L363F | Missense Mutation (SNP) | VAF 182/628 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RELN | c.4618G>A p.G1540R | Missense Mutation (SNP) | VAF 61/526 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMBP3 | c.4126C>T p.H1376Y | Missense Mutation (SNP) | VAF 129/1366 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS12 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- RYR1 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD4B | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 140/680 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SARDH | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 63/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SART1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 89/498 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SBNO2 | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 77/429 reads (18%) | called by muse, mutect2, varscan2
- SCN1A | c.2104G>A p.D702N (on ENST00000303395 / NM_001202435.3; = p.D691N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SCUBE3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SERPINA2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 58/332 reads (17%) | called by muse, mutect2, varscan2
- SERPINB12 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- SEZ6L | c.2533C>T p.L845F | Missense Mutation (SNP) | VAF 175/571 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SIPA1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 70/437 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIPA1L2 | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 78/583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A3 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SLC24A2 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A5 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by mutect2, varscan2
- SLC52A3 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 220/694 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- SLC9A2 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SLITRK5 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 76/420 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SMIM23 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMOC2 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 47/508 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.747); called by muse, mutect2
- SNED1 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX2 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 107/648 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SPAG6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SPART | c.1432T>A p.Y478N | Missense Mutation (SNP) | VAF 82/454 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPINT1 | c.1070C>T p.T357I (on ENST00000344051 / NM_181642.3; = p.T341I on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 107/587 reads (18%) | PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SUPT20H | c.1592G>A p.R531K (on ENST00000350612 / NM_001014286.3; = p.R532K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/499 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SYBU | c.238G>A p.G80S (on ENST00000276646 / NM_001099754.2; = p.G79S on NM_017786.6) | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX19 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 208/671 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TDRD15 | c.5419C>T p.P1807S | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THUMPD1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLE7 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TMEM215 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 100/544 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFAIP8L2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TOGARAM2 | c.1403G>A p.W468* | Nonsense Mutation (SNP) | VAF 62/378 reads (16%) | called by muse, mutect2, varscan2
- TOP3B | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 164/552 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAF5 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRHR | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TRIP11 | c.3109G>T p.E1037* | Nonsense Mutation (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
- TTC6 | c.3296G>A p.W1099* | Nonsense Mutation (SNP) | VAF 50/311 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.27058G>A p.D9020N (on ENST00000591111; = p.D8093N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/464 reads (13%) | PolyPhen benign (0.274); called by muse, mutect2, varscan2
- USP45 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 51/497 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UTP4 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- VWCE | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 86/428 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WASF3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 96/543 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR25 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, varscan2
- WDR3 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 78/360 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZDBF2 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 74/417 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF277 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 186/821 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF292 | c.5917C>T p.H1973Y | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ZNF521 | c.3556C>T p.P1186S | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- ZNF550 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 92/445 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF667 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 81/474 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF678 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF735 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ZNF780A | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 82/437 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF786 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 228/722 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, varscan2
- ZNF816 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF845 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZNF865 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 116/595 reads (19%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- ABCA13 | c.10008C>T p.Y3336= | Silent (SNP) | VAF 91/320 reads (28%) | catalogued as rs1223602080; called by muse, mutect2, varscan2
- ABCA5 | c.1107T>C p.I369= | Silent (SNP) | VAF 46/237 reads (19%) | called by mutect2, varscan2
- ABCG2 | c.1356G>A p.K452= | Silent (SNP) | VAF 52/326 reads (16%) | catalogued as rs774119423, COSV52947046; called by muse, mutect2, varscan2
- ABHD1 | c.27G>A p.Q9= | Silent (SNP) | VAF 44/270 reads (16%) | called by muse, mutect2, varscan2
- ACSM6 | c.27C>T p.S9= | Silent (SNP) | VAF 66/344 reads (19%) | called by muse, mutect2, varscan2
- ADAM18 | c.93G>A p.R31= | Silent (SNP) | VAF 65/367 reads (18%) | called by muse, mutect2, varscan2
- ADAM2 | c.852G>A p.G284= | Silent (SNP) | VAF 58/393 reads (15%) | catalogued as COSV55868224; called by muse, mutect2, varscan2
- ADAMTS16 | c.447C>T p.G149= | Silent (SNP) | VAF 77/439 reads (18%) | catalogued as rs778584055; called by muse, mutect2, varscan2
- ADAMTS18 | c.1788G>A p.S596= | Silent (SNP) | VAF 77/477 reads (16%) | catalogued as rs754376684, COSV51422252; called by muse, mutect2, varscan2
- ADCY7 | c.1056G>A p.L352= | Silent (SNP) | VAF 70/400 reads (18%) | catalogued as COSV99576158; called by muse, mutect2, varscan2
- ADGRB1 | c.2155C>T p.L719= | Silent (SNP) | VAF 82/388 reads (21%) | called by muse, mutect2, varscan2
- ADGRL1 | c.2124C>T p.I708= (on ENST00000340736 / NM_001008701.3; = p.I703= on NM_014921.5) | Silent (SNP) | VAF 85/409 reads (21%) | catalogued as rs1441920533; called by muse, mutect2, varscan2
- AKAP3 | c.2511G>A p.V837= | Silent (SNP) | VAF 84/424 reads (20%) | called by muse, mutect2, varscan2
- ANKFN1 | c.663C>T p.A221= | Silent (SNP) | VAF 133/445 reads (30%) | catalogued as COSV59446838; called by muse, mutect2, varscan2
- APBB1 | c.189C>T p.G63= | Silent (SNP) | VAF 91/483 reads (19%) | called by muse, mutect2, varscan2
- APEX2 | c.1362A>T p.S454= | Silent (SNP) | VAF 112/331 reads (34%) | called by muse, mutect2, varscan2
- ARID2 | c.4725G>A p.Q1575= | Silent (SNP) | VAF 60/416 reads (14%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.1203C>T p.F401= | Silent (SNP) | VAF 183/498 reads (37%) | called by muse, mutect2, varscan2
- ATPAF2 | c.639G>A p.Q213= | Silent (SNP) | VAF 66/331 reads (20%) | called by muse, mutect2, varscan2
- BAG6 | c.747C>G p.A249= | Silent (SNP) | VAF 76/854 reads (9%) | called by muse, mutect2
- BAIAP3 | c.2586C>T p.H862= | Silent (SNP) | VAF 52/446 reads (12%) | catalogued as rs1296266873; called by muse, mutect2, varscan2
- BNC1 | c.543A>G p.E181= | Silent (SNP) | VAF 81/437 reads (19%) | called by muse, mutect2, varscan2
- BNIP5 | c.1194C>T p.S398= | Silent (SNP) | VAF 42/488 reads (9%) | catalogued as rs538282080; called by muse, mutect2
- BRAT1 | c.387C>T p.S129= | Silent (SNP) | VAF 183/693 reads (26%) | called by muse, mutect2, varscan2
- BRINP2 | c.1557G>A p.Q519= | Silent (SNP) | VAF 153/477 reads (32%) | called by muse, mutect2, varscan2
- C8B | c.426G>A p.G142= | Silent (SNP) | VAF 56/353 reads (16%) | catalogued as rs1288393838; called by muse, mutect2, varscan2
- CACNA1I | c.1233G>A p.L411= | Silent (SNP) | VAF 152/591 reads (26%) | called by muse, mutect2, varscan2
- CALHM1 | c.834G>A p.T278= | Silent (SNP) | VAF 89/483 reads (18%) | catalogued as rs756216448, COSV53297965; called by muse, mutect2, varscan2
- CALHM5 | c.528G>A p.Q176= | Silent (SNP) | VAF 88/269 reads (33%) | called by muse, mutect2, varscan2
- CAPN12 | c.702G>A p.K234= | Silent (SNP) | VAF 51/345 reads (15%) | called by muse, mutect2, varscan2
- CARD11 | c.1833C>T p.F611= | Silent (SNP) | VAF 139/541 reads (26%) | catalogued as rs779682365; called by muse, mutect2, varscan2
- CBL | c.285C>T p.L95= | Silent (SNP) | VAF 43/330 reads (13%) | called by muse, mutect2, varscan2
- CCDC116 | c.822G>A p.K274= | Silent (SNP) | VAF 135/491 reads (27%) | called by muse, mutect2, varscan2
- CDC42BPA | c.5151C>T p.T1717= (on ENST00000334218 / NM_001366019.2; = p.T1704= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 152/551 reads (28%) | called by muse, mutect2, varscan2
- CDH11 | c.1068G>A p.P356= | Silent (SNP) | VAF 79/452 reads (17%) | catalogued as rs139053832; called by muse, mutect2, varscan2
- CEP135 | c.1339C>T p.L447= | Silent (SNP) | VAF 47/286 reads (16%) | catalogued as COSV57257845; called by muse, mutect2, varscan2
- CFAP251 | c.2856C>T p.F952= | Silent (SNP) | VAF 55/341 reads (16%) | catalogued as COSV56615937; called by muse, mutect2, varscan2
- CFAP47 | c.1614G>A p.S538= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV52888570; called by muse, mutect2, varscan2
- CHRNB4 | c.852C>T p.I284= | Silent (SNP) | VAF 63/435 reads (14%) | catalogued as rs377658350; called by muse, mutect2, varscan2
- CILK1 | c.1335G>A p.K445= (on ENST00000350082 / NM_001375397.1; = p.K438= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/388 reads (11%) | called by muse, mutect2
- CLEC18C | c.264C>T p.L88= | Silent (SNP) | VAF 55/876 reads (6%) | called by muse, mutect2
- CLIP3 | c.1134C>T p.P378= | Silent (SNP) | VAF 85/471 reads (18%) | catalogued as COSV53324773; called by muse, mutect2, varscan2
- CNNM1 | c.174G>A p.E58= | Silent (SNP) | VAF 125/656 reads (19%) | catalogued as rs1466410526; called by muse, mutect2, varscan2
- CNTNAP5 | c.1758C>T p.I586= | Silent (SNP) | VAF 67/309 reads (22%) | catalogued as rs1231318164, COSV70471857, COSV70492617; called by muse, mutect2, varscan2
- COL4A3 | c.2649G>A p.G883= | Silent (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
- CRB1 | c.1707C>T p.F569= | Silent (SNP) | VAF 119/394 reads (30%) | catalogued as rs201885772, COSV66329457; called by muse, varscan2
- CRY2 | c.1116C>T p.I372= | Silent (SNP) | VAF 109/571 reads (19%) | called by muse, mutect2, varscan2
- CSF2RB | c.1974G>A p.P658= | Silent (SNP) | VAF 92/665 reads (14%) | catalogued as rs759919346; called by muse, mutect2, varscan2
- CT47B1 | c.261C>T p.I87= | Silent (SNP) | VAF 133/390 reads (34%) | catalogued as COSV64890651; called by muse, mutect2, varscan2
- DAGLA | c.2925C>T p.L975= | Silent (SNP) | VAF 106/573 reads (18%) | catalogued as rs541168855; called by muse, mutect2, varscan2
- DDC | c.1336C>T p.L446= | Silent (SNP) | VAF 155/628 reads (25%) | called by muse, mutect2, varscan2
- DENND5B | c.1506C>A p.L502= | Silent (SNP) | VAF 77/437 reads (18%) | catalogued as COSV60907751; called by muse, mutect2, varscan2
- DGKB | c.2283G>A p.E761= | Silent (SNP) | VAF 147/576 reads (26%) | catalogued as rs773691602; called by muse, mutect2, varscan2
- DHTKD1 | c.1854C>T p.I618= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as COSV53802665; called by muse, mutect2
- DHX35 | c.1305A>G p.K435= | Silent (SNP) | VAF 51/376 reads (14%) | called by muse, mutect2, varscan2
- DISC1 | c.663G>A p.G221= | Silent (SNP) | VAF 103/642 reads (16%) | called by muse, mutect2, varscan2
- DMXL1 | c.7668C>T p.T2556= | Silent (SNP) | VAF 117/404 reads (29%) | catalogued as rs186037183, COSV60719737; called by muse, mutect2, varscan2
- DNAH2 | c.4029G>A p.G1343= | Silent (SNP) | VAF 67/431 reads (16%) | called by muse, mutect2, varscan2
- DNAH3 | c.10011G>A p.T3337= | Silent (SNP) | VAF 66/336 reads (20%) | catalogued as rs367808003; called by muse, mutect2, varscan2
- DNAH5 | c.10059C>T p.S3353= | Silent (SNP) | VAF 98/564 reads (17%) | called by muse, mutect2, varscan2
- DNAH8 | c.9273G>A p.K3091= | Silent (SNP) | VAF 34/398 reads (9%) | catalogued as COSV59478529; called by muse, mutect2
- DNAH9 | c.3246C>T p.D1082= | Silent (SNP) | VAF 88/414 reads (21%) | catalogued as rs374619249; called by muse, mutect2, varscan2
- DNMT3B | c.2049C>T p.R683= | Silent (SNP) | VAF 100/480 reads (21%) | called by muse, mutect2, varscan2
- DOLPP1 | c.345C>T p.F115= | Silent (SNP) | VAF 41/250 reads (16%) | catalogued as rs767726929; called by muse, mutect2, varscan2
- DPRX | c.537C>T p.G179= | Silent (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2, varscan2
- DUXA | c.87C>T p.I29= | Silent (SNP) | VAF 76/369 reads (21%) | catalogued as COSV73729564; called by muse, mutect2, varscan2
- DYDC2 | c.123G>A p.R41= | Silent (SNP) | VAF 41/272 reads (15%) | called by muse, mutect2, varscan2
- EIF2B2 | c.63C>T p.T21= | Silent (SNP) | VAF 79/409 reads (19%) | catalogued as rs774585521; called by muse, mutect2, varscan2
- EIF3G | c.864C>T p.H288= | Silent (SNP) | VAF 54/393 reads (14%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1152T>A p.A384= | Silent (SNP) | VAF 105/367 reads (29%) | called by muse, mutect2, varscan2
- ENG | c.1041G>A p.K347= | Silent (SNP) | VAF 54/415 reads (13%) | catalogued as rs367734769; called by muse, mutect2, varscan2
- EPAS1 | c.273C>T p.Y91= | Silent (SNP) | VAF 77/382 reads (20%) | called by muse, mutect2, varscan2
- ERCC6 | c.214C>T p.L72= | Silent (SNP) | VAF 77/480 reads (16%) | catalogued as rs1429295513; called by muse, mutect2, varscan2
- ERI2 | c.30T>C p.L10= | Silent (SNP) | VAF 55/296 reads (19%) | called by muse, mutect2, varscan2
- ERICH3 | c.1059C>T p.F353= | Silent (SNP) | VAF 68/408 reads (17%) | catalogued as rs769875646, COSV58607407; called by muse, mutect2, varscan2
- FAM107A | c.27G>A p.R9= | Silent (SNP) | VAF 52/297 reads (18%) | called by muse, mutect2, varscan2
- FAM171A2 | c.57G>A p.L19= | Silent (SNP) | VAF 72/379 reads (19%) | catalogued as rs994973657; called by muse, mutect2, varscan2
- FBL | c.372G>A p.S124= | Silent (SNP) | VAF 40/232 reads (17%) | catalogued as rs767505703, COSV55682415; called by muse, mutect2, varscan2
- FBLN7 | c.1284C>T p.S428= | Silent (SNP) | VAF 67/512 reads (13%) | called by muse, mutect2, varscan2
- FOXD4 | c.705C>T p.A235= | Silent (SNP) | VAF 65/384 reads (17%) | called by muse, mutect2, varscan2
- FREM3 | c.5496C>T p.F1832= | Silent (SNP) | VAF 57/378 reads (15%) | called by muse, mutect2, varscan2
- FSIP2 | c.6984C>T p.F2328= | Silent (SNP) | VAF 65/382 reads (17%) | catalogued as rs865971307; called by muse, mutect2, varscan2
- GALT | c.700C>T p.L234= | Silent (SNP) | VAF 61/315 reads (19%) | catalogued as rs751351126; called by muse, mutect2, varscan2
- GHR | c.1584C>T p.F528= | Silent (SNP) | VAF 102/531 reads (19%) | catalogued as COSV50107699; called by muse, mutect2, varscan2
- GOLGA8S | c.1749G>A p.R583= | Silent (SNP) | VAF 90/568 reads (16%) | called by muse, mutect2, varscan2
- GP1BA | c.85C>T p.L29= | Silent (SNP) | VAF 84/447 reads (19%) | called by muse, mutect2, varscan2
- GPR158 | c.1393C>T p.L465= | Silent (SNP) | VAF 47/290 reads (16%) | called by muse, mutect2, varscan2
- GPRC5B | c.822C>T p.I274= | Silent (SNP) | VAF 88/434 reads (20%) | called by muse, mutect2, varscan2
- GPRC5C | c.915C>T p.I305= (on ENST00000652232; = p.I260= on NM_018653.4) | Silent (SNP) | VAF 106/589 reads (18%) | catalogued as rs1010914923, COSV61237935; called by muse, mutect2, varscan2
- GPT | c.582C>T p.A194= | Silent (SNP) | VAF 80/644 reads (12%) | called by muse, mutect2, varscan2
- GRM8 | c.1947C>T p.S649= | Silent (SNP) | VAF 119/664 reads (18%) | catalogued as COSV58808944; called by muse, mutect2, varscan2
- GSTM5 | c.153C>T p.F51= | Silent (SNP) | VAF 77/463 reads (17%) | catalogued as COSV56658088; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1911C>T p.S637= | Silent (SNP) | VAF 184/636 reads (29%) | called by muse, mutect2, varscan2
- HCFC1 | c.4635C>T p.A1545= | Silent (SNP) | VAF 25/385 reads (6%) | called by muse, mutect2
- HYDIN | c.993C>T p.F331= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.225T>C p.G75= | Silent (SNP) | VAF 95/483 reads (20%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.93C>T p.F31= | Silent (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- ILDR1 | c.1083C>A p.P361= (on ENST00000344209 / NM_001199799.2; = p.P317= on NM_175924.4) | Silent (SNP) | VAF 87/476 reads (18%) | called by muse, mutect2, varscan2
- INPP5E | c.1221G>A p.L407= | Silent (SNP) | VAF 65/342 reads (19%) | catalogued as rs775567331; called by muse, mutect2, varscan2
- IP6K3 | c.462C>T p.A154= | Silent (SNP) | VAF 50/608 reads (8%) | called by muse, mutect2
- ITGAM | c.1836G>A p.L612= (on ENST00000648685 / NM_001145808.2; = p.L611= on NM_000632.4) | Silent (SNP) | VAF 47/244 reads (19%) | called by muse, mutect2, varscan2
- ITGAV | c.2967C>T p.P989= | Silent (SNP) | VAF 65/348 reads (19%) | called by muse, mutect2, varscan2
- IVL | c.900G>A p.E300= | Silent (SNP) | VAF 201/676 reads (30%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1281G>A p.G427= | Silent (SNP) | VAF 62/412 reads (15%) | catalogued as COSV99288368; called by muse, varscan2
- KCNT1 | c.3021C>T p.F1007= (on ENST00000488444; = p.F1026= on NM_020822.3) | Silent (SNP) | VAF 78/359 reads (22%) | called by muse, mutect2, varscan2
- KCNT2 | c.2019T>C p.P673= | Silent (SNP) | VAF 42/295 reads (14%) | called by muse, mutect2, varscan2
- KCTD14 | c.309C>T p.I103= | Silent (SNP) | VAF 74/450 reads (16%) | catalogued as COSV62001990; called by muse, mutect2, varscan2
- KHDC3L | c.261C>T p.I87= | Silent (SNP) | VAF 145/471 reads (31%) | catalogued as COSV64869030; called by muse, mutect2, varscan2
- KIAA1217 | c.2211G>A p.K737= | Silent (SNP) | VAF 61/293 reads (21%) | catalogued as rs1411895699; called by muse, mutect2, varscan2
- KIF2B | c.873C>T p.I291= | Silent (SNP) | VAF 91/551 reads (17%) | catalogued as COSV52130684; called by muse, mutect2, varscan2
- KRT14 | c.99C>T p.S33= | Silent (SNP) | VAF 98/622 reads (16%) | catalogued as rs767746944; called by muse, mutect2, varscan2
- KRT2 | c.1359G>A p.K453= | Silent (SNP) | VAF 64/280 reads (23%) | catalogued as COSV59009254; called by muse, mutect2, varscan2
- KRTAP5-3 | c.96C>T p.G32= | Silent (SNP) | VAF 121/714 reads (17%) | called by muse, mutect2, varscan2
- LAMA5 | c.5238C>T p.F1746= | Silent (SNP) | VAF 155/357 reads (43%) | called by muse, mutect2, varscan2
- LAMB2 | c.1912T>C p.L638= | Silent (SNP) | VAF 69/307 reads (22%) | called by muse, mutect2, varscan2
- LCN9 | c.381C>T p.F127= | Silent (SNP) | VAF 60/408 reads (15%) | called by muse, mutect2, varscan2
- LCT | c.618C>T p.Y206= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as rs771272153; called by muse, mutect2, varscan2
- LHX6 | c.588C>T p.A196= (on ENST00000373755 / NM_001242334.2; = p.A225= on NM_014368.5) | Silent (SNP) | VAF 56/229 reads (24%) | catalogued as rs752726361; called by muse, mutect2, varscan2
- LIFR | c.1512A>C p.L504= | Silent (SNP) | VAF 70/414 reads (17%) | called by muse, mutect2, varscan2
- LMOD1 | c.1212C>T p.I404= | Silent (SNP) | VAF 116/597 reads (19%) | called by muse, mutect2, varscan2
- MAGEB10 | c.321C>A p.P107= | Silent (SNP) | VAF 103/293 reads (35%) | called by muse, mutect2, varscan2
- MATK | c.195G>A p.G65= (on ENST00000310132 / NM_139355.3; = p.G66= on NM_002378.4) | Silent (SNP) | VAF 101/523 reads (19%) | catalogued as rs1448818814; called by muse, mutect2, varscan2
- MCMDC2 | c.322C>T p.L108= | Silent (SNP) | VAF 43/261 reads (16%) | catalogued as COSV100552062; called by muse, mutect2, varscan2
- MGAM2 | c.381C>T p.F127= | Silent (SNP) | VAF 70/756 reads (9%) | catalogued as rs1317891983; called by muse, mutect2
- MOB3A | c.378C>T p.I126= | Silent (SNP) | VAF 71/345 reads (21%) | catalogued as rs138655962; called by muse, mutect2, varscan2
- MPP7 | c.420C>T p.I140= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs267602464, COSV61731856; called by muse, mutect2, varscan2
- MS4A14 | c.2028C>T p.P676= | Silent (SNP) | VAF 27/210 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.35205C>T p.I11735= | Silent (SNP) | VAF 81/439 reads (18%) | called by muse, mutect2, varscan2
- MUC22 | c.771C>T p.T257= | Silent (SNP) | VAF 71/833 reads (9%) | called by muse, mutect2
- MXRA5 | c.1767G>A p.K589= | Silent (SNP) | VAF 83/232 reads (36%) | called by muse, mutect2, varscan2
- MYH4 | c.4104C>T p.A1368= | Silent (SNP) | VAF 103/529 reads (19%) | called by muse, mutect2, varscan2
- MYO1E | c.465C>T p.A155= | Silent (SNP) | VAF 59/351 reads (17%) | called by muse, mutect2, varscan2
- NAV3 | c.6414C>T p.F2138= (on ENST00000397909 / NM_001024383.2; = p.F2116= on NM_014903.6) | Silent (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
- NCAPD2 | c.1119C>T p.G373= | Silent (SNP) | VAF 99/475 reads (21%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1182G>A p.K394= | Silent (SNP) | VAF 69/380 reads (18%) | called by muse, mutect2, varscan2
- NLGN4Y | c.1032C>T p.I344= | Silent (SNP) | VAF 112/351 reads (32%) | called by muse, mutect2, varscan2
- NLRP1 | c.657C>T p.I219= | Silent (SNP) | VAF 43/250 reads (17%) | called by muse, mutect2, varscan2
- NLRP3 | c.1731C>T p.F577= | Silent (SNP) | VAF 94/482 reads (20%) | called by muse, mutect2, varscan2
- NME7 | c.369C>T p.L123= | Silent (SNP) | VAF 71/235 reads (30%) | catalogued as rs752992035; called by muse, mutect2, varscan2
- NOC4L | c.1128C>T p.A376= | Silent (SNP) | VAF 95/571 reads (17%) | called by muse, mutect2, varscan2
- NOS3 | c.2976C>T p.F992= | Silent (SNP) | VAF 175/599 reads (29%) | called by muse, mutect2, varscan2
- NT5C1B | c.531C>T p.L177= (on ENST00000359846 / NM_001199086.2; = p.L117= on NM_033253.4) | Silent (SNP) | VAF 108/591 reads (18%) | catalogued as rs1255518121; called by muse, mutect2, varscan2
- NTRK1 | c.1395C>T p.S465= | Silent (SNP) | VAF 163/540 reads (30%) | catalogued as rs1311708647; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXF1 | c.885C>T p.I295= | Silent (SNP) | VAF 71/371 reads (19%) | catalogued as rs144471031; called by muse, mutect2, varscan2
- OAT | c.183C>T p.A61= | Silent (SNP) | VAF 56/275 reads (20%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1251C>T p.L417= | Silent (SNP) | VAF 97/652 reads (15%) | catalogued as rs565805074; called by muse, mutect2, varscan2
- OR10V1 | c.909G>A p.R303= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- OR51D1 | c.627G>A p.V209= | Silent (SNP) | VAF 89/513 reads (17%) | catalogued as COSV62913881; called by muse, mutect2, varscan2
- OR52K2 | c.903C>T p.I301= | Silent (SNP) | VAF 42/336 reads (13%) | catalogued as rs1183045273, COSV57834631; called by muse, mutect2, varscan2
- OR6C65 | c.186G>A p.R62= | Silent (SNP) | VAF 44/263 reads (17%) | catalogued as COSV65568453; called by muse, mutect2, varscan2
- OR6C75 | c.858C>T p.F286= | Silent (SNP) | VAF 41/343 reads (12%) | catalogued as COSV58552273; called by muse, mutect2, varscan2
- OR6K6 | c.318C>T p.I106= (on ENST00000368144; = p.I82= on NM_001005184.1) | Silent (SNP) | VAF 91/575 reads (16%) | called by muse, mutect2, varscan2
- OVCH1 | c.1650A>G p.V550= | Silent (SNP) | VAF 47/280 reads (17%) | catalogued as rs1363656424; called by muse, mutect2, varscan2
- PAK5 | c.2130C>T p.V710= | Silent (SNP) | VAF 53/393 reads (13%) | called by muse, mutect2, varscan2
- PAK5 | c.1800G>A p.R600= | Silent (SNP) | VAF 120/446 reads (27%) | catalogued as rs866712792, COSV62021450, COSV62022784; called by muse, mutect2, varscan2
- PCDHB2 | c.1917G>A p.K639= | Silent (SNP) | VAF 182/669 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1935C>T p.A645= | Silent (SNP) | VAF 163/611 reads (27%) | catalogued as rs765214655; called by muse, mutect2, varscan2
- PCLO | c.6318G>A p.L2106= | Silent (SNP) | VAF 221/629 reads (35%) | called by muse, mutect2, varscan2
- PDCD4 | c.192G>A p.R64= | Silent (SNP) | VAF 73/467 reads (16%) | called by muse, mutect2, varscan2
- PDE6A | c.171G>A p.E57= | Silent (SNP) | VAF 94/368 reads (26%) | catalogued as COSV99678798; called by muse, mutect2, varscan2
- PDK3 | c.153G>A p.K51= | Silent (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- PGBD1 | c.1599C>T p.F533= | Silent (SNP) | VAF 91/307 reads (30%) | catalogued as rs780789760, COSV52552341, COSV52556097; called by muse, mutect2, varscan2
- PHF21B | c.837C>T p.I279= | Silent (SNP) | VAF 126/457 reads (28%) | catalogued as rs368786424; called by muse, mutect2, varscan2
- PI16 | c.657C>T p.F219= | Silent (SNP) | VAF 16/491 reads (3%) | catalogued as rs1424949809; called by muse, mutect2
- PITPNM3 | c.1719C>T p.L573= | Silent (SNP) | VAF 109/500 reads (22%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.1614A>G p.K538= | Silent (SNP) | VAF 74/359 reads (21%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.582C>T p.A194= | Silent (SNP) | VAF 103/711 reads (14%) | called by muse, mutect2, varscan2
- POLDIP2 | c.1059G>A p.L353= | Silent (SNP) | VAF 60/408 reads (15%) | catalogued as rs1242493230; called by muse, mutect2, varscan2
- PPFIA2 | c.3543G>A p.R1181= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs1480243585, COSV100333706; called by muse, mutect2, varscan2
- PRKCB | c.1116C>T p.I372= | Silent (SNP) | VAF 73/372 reads (20%) | catalogued as rs1469405735, COSV57804626; called by muse, mutect2, varscan2
- PRKG2 | c.1485G>A p.Q495= | Silent (SNP) | VAF 67/406 reads (17%) | called by muse, mutect2, varscan2
- PRR36 | c.2856C>T p.L952= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- PRR5 | c.153C>T p.I51= (on ENST00000336985 / NM_181333.4; = p.I42= on NM_015366.4) | Silent (SNP) | VAF 18/566 reads (3%) | catalogued as rs1434202489, COSV99134759; called by muse, mutect2
- PTPN21 | c.342G>A p.E114= | Silent (SNP) | VAF 57/284 reads (20%) | catalogued as COSV60849469; called by muse, mutect2, varscan2
- PTPRS | c.2886C>T p.I962= | Silent (SNP) | VAF 88/474 reads (19%) | called by muse, mutect2, varscan2
- PUM1 | c.1980C>T p.L660= | Silent (SNP) | VAF 87/553 reads (16%) | called by muse, mutect2, varscan2
- PYGM | c.2166T>A p.L722= | Silent (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- RAD23B | c.984A>G p.L328= | Silent (SNP) | VAF 47/371 reads (13%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1087T>C p.L363= | Silent (SNP) | VAF 190/640 reads (30%) | catalogued as COSV54127939; called by muse, mutect2
- RBL2 | c.603C>T p.F201= | Silent (SNP) | VAF 33/271 reads (12%) | called by muse, mutect2, varscan2
- REG1B | c.24C>T p.F8= | Silent (SNP) | VAF 79/354 reads (22%) | catalogued as rs868243041, COSV59304536; called by muse, mutect2, varscan2
- RELN | c.6834G>A p.L2278= | Silent (SNP) | VAF 86/777 reads (11%) | called by muse, mutect2, varscan2
- RFPL1 | c.357G>A p.R119= | Silent (SNP) | VAF 44/422 reads (10%) | called by muse, mutect2, varscan2
- RGS6 | c.264C>T p.I88= | Silent (SNP) | VAF 55/323 reads (17%) | catalogued as rs151307395, COSV59593822; called by muse, mutect2, varscan2
- RGSL1 | c.3036G>A p.S1012= | Silent (SNP) | VAF 42/324 reads (13%) | catalogued as rs1014175979; called by muse, mutect2, varscan2
- RNF180 | c.1374G>A p.R458= | Silent (SNP) | VAF 99/564 reads (18%) | called by muse, mutect2, varscan2
- RNF180 | c.1543C>T p.L515= | Silent (SNP) | VAF 57/339 reads (17%) | catalogued as rs1561265628; called by muse, mutect2, varscan2
- ROS1 | c.6798G>A p.T2266= | Silent (SNP) | VAF 55/574 reads (10%) | catalogued as rs367838842; called by muse, mutect2
- RPS4X | c.156T>A p.L52= | Silent (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- RTL1 | c.4076G>A p.*1359= | Silent (SNP) | VAF 43/247 reads (17%) | catalogued as COSV66017227; called by muse, mutect2, varscan2
- RTL4 | c.621C>T p.D207= | Silent (SNP) | VAF 80/249 reads (32%) | catalogued as COSV61205569; called by muse, mutect2, varscan2
- SALL1 | c.2961G>A p.G987= | Silent (SNP) | VAF 62/388 reads (16%) | called by muse, mutect2, varscan2
- SARS2 | c.129C>T p.L43= | Silent (SNP) | VAF 72/450 reads (16%) | catalogued as COSV99671475; called by muse, mutect2, varscan2
- SCN11A | c.861C>T p.D287= | Silent (SNP) | VAF 46/322 reads (14%) | called by muse, mutect2, varscan2
- SCN8A | c.5721G>A p.R1907= | Silent (SNP) | VAF 89/480 reads (19%) | catalogued as rs766207565; called by muse, mutect2, varscan2
- SIRPB1 | c.378G>A p.G126= | Silent (SNP) | VAF 163/601 reads (27%) | catalogued as COSV99498481; called by muse, mutect2, varscan2
- SKOR2 | c.354C>T p.I118= | Silent (SNP) | VAF 56/329 reads (17%) | called by muse, mutect2, varscan2
- SLC26A7 | c.372G>A p.Q124= | Silent (SNP) | VAF 98/476 reads (21%) | called by muse, mutect2, varscan2
- SLC2A9 | c.21G>A p.R7= | Silent (SNP) | VAF 56/342 reads (16%) | called by muse, mutect2, varscan2
- SLC30A7 | c.10C>T p.L4= | Silent (SNP) | VAF 50/356 reads (14%) | catalogued as rs748214127; called by muse, mutect2, varscan2
- SLC38A1 | c.37T>C p.L13= | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as COSV101284147; called by muse, mutect2, varscan2
- SLC44A5 | c.1065C>T p.I355= | Silent (SNP) | VAF 67/383 reads (17%) | called by muse, mutect2, varscan2
- SLC52A3 | c.792C>T p.S264= | Silent (SNP) | VAF 217/694 reads (31%) | called by muse, mutect2
- SLC5A2 | c.1467C>T p.L489= | Silent (SNP) | VAF 68/398 reads (17%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1971G>A p.K657= | Silent (SNP) | VAF 47/308 reads (15%) | catalogued as rs1162975590; called by muse, mutect2, varscan2
- SLCO5A1 | c.1434C>T p.I478= | Silent (SNP) | VAF 40/262 reads (15%) | catalogued as rs756829489, COSV52661454; called by muse, varscan2
- SP140 | c.2595G>A p.G865= | Silent (SNP) | VAF 44/253 reads (17%) | catalogued as COSV100614174; called by muse, mutect2, varscan2
- SPEF2 | c.3222G>T p.P1074= | Silent (SNP) | VAF 75/442 reads (17%) | catalogued as COSV61544863; called by muse, mutect2, varscan2
- STX4 | c.219C>T p.P73= | Silent (SNP) | VAF 42/307 reads (14%) | catalogued as rs1302250222, COSV58267843; called by muse, mutect2, varscan2
- SYAP1 | c.921C>T p.A307= | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as rs1371955933; called by muse, mutect2, varscan2
- SYNE1 | c.2910G>A p.L970= (on ENST00000367255 / NM_182961.4; = p.L977= on NM_033071.3) | Silent (SNP) | VAF 30/365 reads (8%) | called by muse, mutect2
- TBC1D9B | c.3582C>T p.T1194= (on ENST00000356834 / NM_198868.3; = p.T1177= on NM_015043.4) | Silent (SNP) | VAF 139/900 reads (15%) | catalogued as rs1318535789; called by muse, mutect2, varscan2
- TCF3 | c.1203C>T p.I401= | Silent (SNP) | VAF 84/427 reads (20%) | catalogued as rs780703673; called by muse, mutect2, varscan2
- TEK | c.2232G>A p.G744= | Silent (SNP) | VAF 54/282 reads (19%) | catalogued as rs755057652; called by muse, mutect2, varscan2
- THRSP | c.408G>A p.R136= | Silent (SNP) | VAF 60/351 reads (17%) | catalogued as COSV55246064; called by muse, mutect2, varscan2
- THSD7A | c.447G>A p.G149= | Silent (SNP) | VAF 158/573 reads (28%) | catalogued as rs1345147412, COSV101448561; called by muse, mutect2, varscan2
- TLCD3B | c.666C>T p.P222= | Silent (SNP) | VAF 119/666 reads (18%) | catalogued as rs779686993; called by muse, mutect2, varscan2
- TMEM125 | c.210G>A p.T70= | Silent (SNP) | VAF 89/495 reads (18%) | catalogued as rs573732317; called by muse, mutect2, varscan2
- TMEM174 | c.453G>A p.G151= | Silent (SNP) | VAF 193/612 reads (32%) | called by muse, mutect2, varscan2
- TMEM225B | c.276C>T p.I92= | Silent (SNP) | VAF 234/664 reads (35%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.855C>T p.Y285= | Silent (SNP) | VAF 61/416 reads (15%) | called by muse, mutect2, varscan2
- TMX4 | c.384C>T p.F128= | Silent (SNP) | VAF 59/476 reads (12%) | catalogued as rs756824619, COSV55682429; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.705A>G p.E235= | Silent (SNP) | VAF 71/462 reads (15%) | called by muse, mutect2, varscan2
- TP53BP1 | c.3651C>T p.L1217= | Silent (SNP) | VAF 41/294 reads (14%) | catalogued as COSV55497984; called by muse, mutect2, varscan2
- TRANK1 | c.6540G>A p.S2180= | Silent (SNP) | VAF 57/416 reads (14%) | catalogued as rs867659681, COSV57143588; called by muse, mutect2, varscan2
- TRIM58 | c.861G>A p.R287= | Silent (SNP) | VAF 88/278 reads (32%) | catalogued as rs1336957439, COSV63569020; called by muse, mutect2, varscan2
- TRIM58 | c.1051C>T p.L351= | Silent (SNP) | VAF 108/588 reads (18%) | called by muse, mutect2, varscan2
- TRPV5 | c.1761G>A p.Q587= | Silent (SNP) | VAF 254/725 reads (35%) | catalogued as rs199538456, COSV54682997; called by muse, mutect2, varscan2
- TTLL12 | c.1680G>A p.Q560= | Silent (SNP) | VAF 81/560 reads (14%) | catalogued as rs1276501617; called by muse, mutect2, varscan2
- TTN | c.27324G>A p.P9108= (on ENST00000591111; = p.P8181= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/482 reads (15%) | catalogued as rs1448968221, COSV59920730; ClinVar: likely benign; called by muse, varscan2
- TTN | c.24849C>T p.F8283= (on ENST00000591111; = p.F7356= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/415 reads (14%) | catalogued as rs1215707268, COSV60246938; called by muse, mutect2, varscan2
- TTN | c.13161G>A p.R4387= (on ENST00000591111; = p.R4341= on NM_003319.4) | Silent (SNP) | VAF 56/328 reads (17%) | catalogued as COSV59883629; called by muse, mutect2, varscan2
- TUBB2A | c.1170G>T p.R390= | Silent (SNP) | VAF 18/70 reads (26%) | called by mutect2, varscan2
- UGT2A2 | c.15G>A p.R5= | Silent (SNP) | VAF 27/251 reads (11%) | called by muse, mutect2, varscan2
- USP17L4 | c.1185C>T p.G395= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as rs1264449916; called by muse, mutect2, varscan2
- USP54 | c.1578C>T p.T526= | Silent (SNP) | VAF 111/572 reads (19%) | called by muse, mutect2, varscan2
- VPS37C | c.297C>T p.T99= | Silent (SNP) | VAF 81/393 reads (21%) | called by muse, mutect2, varscan2
- WNK2 | c.6705C>T p.P2235= (on ENST00000297954 / NM_001282394.1; = p.P2198= on NM_006648.3) | Silent (SNP) | VAF 80/508 reads (16%) | catalogued as rs762094203; called by muse, varscan2
- ZC3HAV1 | c.2415C>T p.F805= | Silent (SNP) | VAF 116/403 reads (29%) | called by muse, mutect2, varscan2
- ZEB1 | c.2509C>T p.L837= | Silent (SNP) | VAF 65/370 reads (18%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3954G>A p.G1318= | Silent (SNP) | VAF 48/288 reads (17%) | catalogued as COSV50632318; called by muse, mutect2, varscan2
- ZNF14 | c.1197C>T p.T399= | Silent (SNP) | VAF 72/425 reads (17%) | called by muse, mutect2, varscan2
- ZNF467 | c.336C>T p.P112= | Silent (SNP) | VAF 242/717 reads (34%) | called by muse, mutect2, varscan2
- ZNF597 | c.679C>T p.L227= | Silent (SNP) | VAF 68/454 reads (15%) | catalogued as COSV57083518; called by muse, mutect2, varscan2
- ZNF808 | c.1560C>T p.F520= | Silent (SNP) | VAF 70/528 reads (13%) | called by muse, mutect2, varscan2
- ZNF816 | c.1128G>A p.K376= | Silent (SNP) | VAF 68/382 reads (18%) | called by muse, mutect2, varscan2
- ZNF879 | c.1578C>T p.S526= | Silent (SNP) | VAF 268/573 reads (47%) | catalogued as rs776459651; called by muse, mutect2, varscan2
- ADAMTS20 | c.4284+1621G>A | Intron (SNP) | VAF 50/277 reads (18%) | catalogued as rs779870005; called by muse, mutect2, varscan2
- AGAP3 | c.224-1825G>A | Intron (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- ANGEL1 | c.1381-14_1381-12del | Intron (DEL) | VAF 64/439 reads (15%) | called by pindel, varscan2
- CACNA2D4 | c.228-269G>A | Intron (SNP) | VAF 73/430 reads (17%) | called by muse, mutect2, varscan2
- CASR | c.1378-25C>T | Intron (SNP) | VAF 48/270 reads (18%) | called by muse, varscan2
- CASTOR3 | n.437C>T | RNA (SNP) | VAF 61/531 reads (11%) | called by muse, mutect2, varscan2
- CCDC9 | chr19:47272098 G>A | 3'Flank (SNP) | VAF 71/422 reads (17%) | called by muse, mutect2, varscan2
- CDHR1 | chr10:84219171 C>T | 3'Flank (SNP) | VAF 88/538 reads (16%) | catalogued as rs1479714459; called by muse, mutect2
- DCHS2 | n.4617C>T | RNA (SNP) | VAF 16/462 reads (3%) | called by muse, mutect2
- DCHS2 | n.494G>A | RNA (SNP) | VAF 47/277 reads (17%) | catalogued as COSV59727069; called by muse, mutect2, varscan2
- DNAH14 | c.7717-193C>T | Intron (SNP) | VAF 40/247 reads (16%) | catalogued as COSV59902608; called by muse, mutect2, varscan2
- FAM21FP | n.165G>A | RNA (SNP) | VAF 52/413 reads (13%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-31379C>T | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as COSV50100438; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-16226C>T | Intron (SNP) | VAF 52/288 reads (18%) | called by muse, mutect2, varscan2
- KIZ | c.-22G>A | 5'UTR (SNP) | VAF 104/693 reads (15%) | called by muse, mutect2, varscan2
- LIM2 | c.175+109G>A | Intron (SNP) | VAF 47/306 reads (15%) | called by muse, mutect2, varscan2
17 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 17 other) are not listed here.
